Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3552, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3552-01A (Primary Tumor).

Diagnosis:

1. : Resected ileocolic material with a moderately differentiated colorectal adenocarcinoma located in the cecum, measuring a max of 3.8 cm in diameter and with circumscribed infiltration of the pericecal adipose tissue and with ten regional/local lymph node metastases. Tumor-free small and large intestine resection margins. Tumor-free mesenteric resection margin. Evidence of lymphangiosis carcinomatosa also in the perityphlitic adipose tissue as well as in the tunica muscularis propria of the appendix. Tumor-free omental adipose tissue.
2. : Resected colon with circumscribed ulcerous mucous membrane defect displaying a condition following an ablation of a colorectal adenocarcinoma infiltrating the submucosa. No further sections of the neoplasia diagnosed previously. Tumor-free lymph nodes in the region. Tumor-free colon resection margins and accompanying colon wall tourniquet.

Tumor stage relating to 1: pT3, pN2 (10/20) pMX; G2, L1, V0, local R0

Tumor stage relating to 2: pT1, pN0 (0/6) pMX; G2, L0, V0, R0.

Diagnosis:

1. : Resected liver tissue with a bilious hamartoma (so-called Meyenburg complex).
2. : Further tumor-free resected liver with small bile duct cysts and pericystic scarred area.
3. : Superficial resected liver tissue with scarred capsular area. No signs of malignancy and in particular no metastasis of a colon carcinoma in the material at hand.

Source: NCI Genomic Data Commons file ff9a61a9-594b-4262-9a2a-93c6d582470a (TCGA-AA-3552.8E12A8A9-9717-4533-969F-1D9545DE70F0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).